Surgical pathology report (de-identified scan), TCGA case TCGA-24-1419, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1419-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL WITH ADDENDUM

Patient Name

Address:

Gender:

DOB:

Physician(s):

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

DIAGNOSIS:

A. "TUMOR," SITE NOT SPECIFIED, BIOPSY (INCLUDING FS1)

- METASTATIC HIGH GRADE ENDOMETRIOID ADENOCARCINOMA WITH FOCAL HIGH GRADE SEROUS CARCINOMA

B. RIGHT OVARY AND FALLOPIAN TUBE, SALPINGO-OOPHORECTOMY

- HIGH GRADE ENDOMETRIOID ADENOCARCINOMA WITH VERY FOCAL HIGH GRADE SEROUS CARCINOMA (<1%) INVOLVING THE OVARY (SURFACE AND PARENCHYMA) AND PERITUBAL SOFT TISSUE
- SEE COMMENT AND SYNOPSIS

C. LEFT, OVARY AND FALLOPIAN TUBE, SALPINGO-OOPHORECTOMY

- HIGH-GRADE ENDOMETRIOID ADENOCARCINOMA (98%) WITH FOCAL HIGH GRADE SEROUS CARCINOMA (2%), INVOLVING THE OVARIAN PARENCHYMA AND SURFACE
- NO DEFINITIVE FALLOPIAN TUBE IDENTIFIED (ADDITIONAL SECTIONS PENDING, WILL BE REPORTED IN AN ADDENDUM)

D. BLADDER, PERITONEUM, EXCISION

- METASTATIC HIGH GRADE ENDOMETRIOID ADENOCARCINOMA WITH FOCAL HIGH GRADE SEROUS CARCINOMA

E. OMENTUM, EXCISION

- METASTATIC HIGH GRADE ENDOMETRIOID CARCINOMA WITH FOCAL HIGH GRADE SEROUS CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

Intraoperative Consultation:

FS1: Tumor, biopsy

- "Malignant neoplasm, favor Mullerian origin. Final classification deferred to permanents,"

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Microscopic Description and Comment:

Sections of the right and left ovaries show predominantly endometrioid adenocarcinoma (FIGO grade 3) with focal high grade serous carcinoma. Tumor is present on the ovarian surface and within the peritubal soft tissue. A portion of normal right fallopian tube is identified. Immunostains for P53, P16, and WT1 were performed on sections of the right ovarian and left ovarian tumors. These endometrioid areas showed patchy staining for P16. An Immunostain for P53 showed diffuse nuclear staining. An immunostain for WT1 showed diffuse nuclear staining. This immunoprofile supports the above diagnosis.

History:

The patient is a [REDACTED] with a pelvic mass, ascites, and bilateral hydronephrosis. Operative procedure: Examined under anesthesia, exploratory laparotomy, bilateral salpingo-oophorectomy, tumor debulking and omentectomy.

Specimen(s) Received:

A: TUMOR
B: OVARY AND TUBE, RIGHT
C: LEFT ADNEXA
D: BLADDER PERITONEUM
E: OMENTUM

Gross Description:

The specimens are received in five containers of formalin, each labeled [REDACTED]. The first container is labeled "tumor." It contains a white tissue cassette labeled 'FS1' that holds a 0.6 x 0.5 x 0.3 cm tan-white soft tissue mass. Labeled A1(FS1). Jar 0.

The second container is labeled "right tube and ovary." It contains an 11.5 x 6 x 2 cm piece of soft tissue, including a 2 x 1 x 0.9 cm ovary. The ovary has a smooth, glistening, white surface. The cut surface is tan-white, nodular, and friable. A putative fallopian tube is identified measuring 7 x 0.5 cm. It is sectioned to show a pinpoint lumen measuring 0.1 cm in diameter and a completely occluded lumen more proximally. The remaining tissue consists of friable papillary tan soft tissue adherent to the peritoneal surface. Within the soft tissue are multiple firm white nodules ranging from 1 x 1 x 0.5 to 0.3 x 0.3 x 0.2 cm. Labeled B1 to B5 - ovary, entirely submitted; B6 - putative fallopian tube; B7 - tumor. Jar 2.

The third container is labeled "left adnexa." It contains three fragments of soft tissue. The first measures 9.5 x 3.5 x 2.5 cm and contains a 4.5 x 2.9 x 2.6 cm multicystic ovary with a blue-white glistening surface, with a small amount of attached soft tissue and no identifiable attached fallopian tube. Sections show ovarian cysts filled with brown serous fluid. There is a 1 x 0.8 x 1 cm firm white nodule adjacent to the ovarian surface. In addition there are numerous small friable papillary excrescences in the cyst, that measure up to 2 cm in diameter. The adjacent soft tissue is sectioned to show a 4 x 0.8 cm putative fallopian tube with hydrosalpinx, and a 1.2 x 0.5 x 0.4 cm white nodule. No normal fallopian tube is identified. The next largest fragment of soft tissue measures 6.5 x 4 x 2 cm, with a blue-gray, smooth surface with tan-white friable papillary adherent masses measuring up to 3.5 x 2 x 1.5 cm. The friable papillary lesions are sectioned to show firm underlying tan-white soft tissue. The smallest fragment of tissue measures 4.2 x 2 x 1 cm, and consists of unremarkable tan-yellow fibrofatty tissue. Sections show no focal lesions. Labeled C1 to C4 - ovary; C5 - putative fallopian tube; C6 and C7 - tumor; C8 to C10 - additional sections of soft tissue with putative fallopian tube. Jar 2.

The fourth container is labeled "bladder peritoneum." It contains a 6 x 4.5 x 1.4 cm fragment of tan-yellow soft tissue. The outer surface is covered by tan-white nodular soft tissue. The nodules range from < 0.1 cm in diameter to up to 2

[page 3 of 4]
Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

x 1 x 0.5 cm. The cut surface shows a firm white nodular mass abutting the yellow glistening fatty tissue. Labeled D1 and D2. Jar 1.

The fifth container is labeled "omentum." It contains multiple fragments of tan-white fibrofatty tissue ranging from 32 x 16 x 2 cm to 3 x 1 x 3.5 cm. The fatty tissue contains innumerable firm white nodules ranging from 0.1 cm in diameter to areas of confluent firm white tissue measuring 11 x 5 x 3.2 cm. Labeled E1 and E2. Jar 4.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is high grade endometrioid carcinoma with focal high grade serous carcinoma

TUMOR LOCATION (PRIMARY)

Right and left ovaries

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3) or high grade

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present
Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

pT3c/Nx/Mx

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Addenda/Procedures

Addendum Ordered:
Addendum Complete
Addendum Signed On

Status: Signed Out
By:

Addendum Diagnosis

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

No fallopian tube was identified on gross examination or on microscopic examination of the initial sections of the left adnexa. Therefore, additional sections of the left adnexa were submitted (C8-C30) to identify the left fallopian tube. Left fallopian tube was identified with no evidence of malignancy but the carcinoma involves the peritubal soft tissue.

END OF REPORT

Page 4 of 4

Source: NCI Genomic Data Commons file 19fc8703-52d2-4623-9b51-7b07a43d8037 (TCGA-24-1419.0A8C75AA-8031-4F1D-9DBA-9029B009D677.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).